Somatic mutation profile of tumor specimen 0DGL6M from CCDI case PBBSYL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,404 days).
Specimen 0DGL6M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c58d64-4918-41c0-a9a0-c02056aab3fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGL6P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60f43aff-3959-44d0-8382-4b4d34a7f6d1

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 4, Frame Shift Del 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 451/1158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200798538, CM1211843, COSV57656229; called by muse, mutect2, varscan2
- KIF13A | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 42/1050 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1252217511; called by muse, mutect2
- ATR | c.4011_4012del p.V1338Afs*37 | Frame Shift Del (DEL) | VAF 464/1908 reads (24%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 94/1660 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- MMP3 | c.521T>A p.F174Y | Missense Mutation (SNP) | VAF 38/1362 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NXF1 | c.1782G>C p.W594C | Missense Mutation (SNP) | VAF 509/1216 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCH1 | c.1308C>G p.D436E | Missense Mutation (SNP) | VAF 1313/1449 reads (91%) | SIFT tolerated (0.44); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FBLN1 | c.1158G>A p.T386= | Silent (SNP) | VAF 41/1344 reads (3%) | catalogued as rs1296655358; called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- ATP5PD | c.292-50G>A | Intron (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- ATP5PD | c.292-51G>A | Intron (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 20/222 reads (9%) | catalogued as COSV99987084; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 12/95 reads (13%) | called by muse, varscan2
